Somatic mutation profile of tumor specimen TCGA-AR-A1AV-01A (aliquot TCGA-AR-A1AV-01A-21D-A12Q-09) from TCGA case TCGA-AR-A1AV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.1 years (24,875 days).
Specimen TCGA-AR-A1AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63cb3eca-ff94-4021-ac48-10eced0cd6df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AV-10A (Blood Derived Normal), aliquot TCGA-AR-A1AV-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2edc4618-7337-4f20-9551-48ac36da4eaa

The open-access MAF lists 43 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 6, Frame Shift Del 4, Nonsense Mutation 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 141/171 reads (82%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKLE2 | c.1610A>G p.K537R | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61710900, COSV61711037; called by muse, mutect2, varscan2
- B3GNT7 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV55007286; called by muse, mutect2, varscan2
- BACH2 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs576225753, COSV57590828; called by muse, mutect2, varscan2
- CPNE2 | c.1394T>C p.M465T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1350004993, COSV51964136; called by muse, mutect2, varscan2
- DMTN | c.787A>T p.I263F | Missense Mutation (SNP) | VAF 87/156 reads (56%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.593); catalogued as COSV56113854; called by muse, mutect2, varscan2
- DPP8 | c.550A>C p.S184R (on ENST00000341861 / NM_001320875.2; = p.S168R on NM_017743.6) | Missense Mutation (SNP) | VAF 91/423 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV55681613; called by muse, mutect2, varscan2
- EIF3I | c.680_681del p.R227Hfs*15 | Frame Shift Del (DEL) | VAF 41/157 reads (26%) | catalogued as COSV61890197; called by mutect2, pindel, varscan2
- GRIK1 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV58727243; called by muse, mutect2, varscan2
- HTR2A | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs539430264, COSV66327600; called by muse, mutect2, varscan2
- INSRR | c.2909A>G p.D970G | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63876034; called by muse, mutect2, varscan2
- KAT6B | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV99767045; called by muse, mutect2
- LRBA | c.6982T>A p.L2328M | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as COSV63960861; called by muse, mutect2, varscan2
- MED15 | c.1481C>T p.T494M (on ENST00000263205 / NM_001003891.3; = p.T454M on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.781); catalogued as rs755070537, COSV53032054; called by muse, mutect2, varscan2
- MEFV | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs144998416; called by muse, mutect2, varscan2
- NEMF | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV53594000, COSV53595691; called by muse, mutect2, varscan2
- NUTF2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs1245639763, COSV54645249; called by muse, mutect2, varscan2
- PARD3 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs566752362, COSV60757269; called by muse, mutect2, varscan2
- PDGFRA | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763325080, COSV57270253, COSV57271649; called by muse, mutect2, varscan2
- PDZRN3 | c.3154G>A p.D1052N | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs755552126, COSV55200910; called by muse, mutect2, varscan2
- PRKG2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV52329361; called by muse, mutect2, varscan2
- SEPTIN4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 73/340 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772182274, COSV57898217; called by muse, mutect2, varscan2
- SETD5 | c.2198C>A p.A733E | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56715368; called by muse, mutect2, varscan2
- SIRPG | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs534699318, COSV53809068, COSV99403805; called by muse, mutect2, varscan2
- SLC2A3 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV50005021, COSV50005698; called by muse, mutect2, varscan2
- STRIP1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.086); catalogued as rs1468324429, COSV63929976; called by muse, mutect2, varscan2
- TAF4B | c.2267C>G p.S756C | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52308106; called by muse, mutect2, varscan2
- TRDN | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as COSV62122682; called by muse, mutect2, varscan2
- VCAN | c.3814G>T p.E1272* | Nonsense Mutation (SNP) | VAF 23/148 reads (16%) | catalogued as COSV54112704, COSV99427054; called by muse, mutect2, varscan2
- WDR20 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54474065; called by muse, mutect2, varscan2
- ZFP30 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs769698824, COSV100665750; called by muse, mutect2, varscan2
- GATA3 | c.1320_1323del p.A441Wfs*33 | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | called by mutect2, pindel, varscan2
- IL12A | c.591_595del p.D198Afs*10 | Frame Shift Del (DEL) | VAF 47/204 reads (23%) | called by mutect2, pindel, varscan2
- MAGI2 | c.620_629del p.A207Vfs*12 | Frame Shift Del (DEL) | VAF 106/448 reads (24%) | called by mutect2, pindel, varscan2
- MIER1 | c.1179_1181del p.E393del (on ENST00000355356 / NM_001077701.3; = p.E410del on NM_020948.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 20/104 reads (19%) | called by pindel, varscan2
- ANKLE1 | c.867G>T p.S289= (on ENST00000394458; = p.S235= on NM_152363.6) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV63921368; called by muse, mutect2, varscan2
- CDC40 | c.1455C>T p.I485= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV57011288; called by muse, mutect2, varscan2
- EHD1 | c.1362G>A p.T454= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs535486154, COSV57735985; called by muse, mutect2, varscan2
- RBMS3 | c.522C>T p.D174= | Silent (SNP) | VAF 133/263 reads (51%) | catalogued as rs566851242, COSV56160161; called by muse, mutect2, varscan2
- TRPM5 | c.1662C>A p.I554= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- TULP4 | c.321C>T p.F107= | Silent (SNP) | VAF 59/266 reads (22%) | catalogued as rs1350527922, COSV65579015; called by muse, mutect2, varscan2
- DCHS2 | n.6462C>T | RNA (SNP) | VAF 22/81 reads (27%) | catalogued as COSV61777065; called by muse, mutect2, varscan2
- PCDH11X | n.559C>T | RNA (SNP) | VAF 40/282 reads (14%) | catalogued as rs2524865; called by muse, mutect2
